Somatic mutation profile of tumor specimen MP2PRT-PAUYIZ-TMP1-A (aliquot MP2PRT-PAUYIZ-TMP1-A-1-0-D-A83P-36) from MP2PRT case MP2PRT-PAUYIZ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.2 years (1,173 days).
Specimen MP2PRT-PAUYIZ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a87b6eb7-931b-49d6-98c1-174a66a62ad6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUYIZ-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUYIZ-NB1-A-1-0-D-A83P-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c440a476-69d4-492f-8375-81a8d278f813

The open-access MAF lists 34 somatic variants for this specimen: 25 protein-altering or splice-affecting, 7 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 7, Nonsense Mutation 3, 5'Flank 1, Frame Shift Ins 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD24 | c.209G>A p.R70H | Missense Mutation (SNP) | VAF 161/401 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.067); catalogued as rs368880588, COSV53670058; called by muse, mutect2, varscan2
- CYP4A11 | c.1189G>A p.V397I | Missense Mutation (SNP) | VAF 192/561 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs778007925; called by muse, mutect2, varscan2
- DCDC1 | c.3541C>T p.Q1181* (on ENST00000597505 / NM_001367979.1; = p.Q288* on NM_020869.3) | Nonsense Mutation (SNP) | VAF 107/274 reads (39%) | catalogued as COSV60306194; called by muse, mutect2, varscan2
- INSYN1 | c.389C>T p.S130L | Missense Mutation (SNP) | VAF 124/368 reads (34%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs200967826, COSV101138754; called by muse, mutect2, varscan2
- KIF12 | c.1889G>A p.R630H (on ENST00000640217; = p.R492H on NM_138424.1) | Missense Mutation (SNP) | VAF 244/603 reads (40%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.009); catalogued as rs747732995; called by muse, mutect2, varscan2
- KRT35 | c.1297G>A p.G433S | Missense Mutation (SNP) | VAF 200/443 reads (45%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs201907377, COSV55843768; called by muse, mutect2, varscan2
- MPP2 | c.541G>A p.V181M (on ENST00000461854 / NM_001278372.2; = p.V157M on NM_005374.5) | Missense Mutation (SNP) | VAF 151/322 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.663); catalogued as COSV52237005, COSV52238291; called by muse, mutect2, varscan2
- SLFN12L | c.956C>G p.P319R (on ENST00000260908 / NM_001363830.1; = p.P337R on NM_001195790.1) | Missense Mutation (SNP) | VAF 18/290 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1166214321; called by muse, mutect2
- SPRY1 | c.887G>C p.R296T | Missense Mutation (SNP) | VAF 134/372 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59338014, COSV59339593; called by muse, mutect2, varscan2
- WDR37 | c.26C>A p.S9* | Nonsense Mutation (SNP) | VAF 97/236 reads (41%) | catalogued as COSV54127192; called by muse, mutect2, varscan2
- ABCC5 | c.2042G>A p.R681Q | Missense Mutation (SNP) | VAF 12/356 reads (3%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2
- ADGRF5 | c.1520C>T p.S507F | Missense Mutation (SNP) | VAF 80/273 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- CLEC16A | c.316G>C p.E106Q | Missense Mutation (SNP) | VAF 110/331 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FOXN2 | c.376G>C p.E126Q | Missense Mutation (SNP) | VAF 64/255 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GOLGA1 | c.1814G>C p.R605T | Missense Mutation (SNP) | VAF 112/366 reads (31%) | SIFT tolerated (0.56); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- IGKV2D-30 | chr2:89937678 CTCCCACAGTGGTACAGCCCTGAACAAAAACCTCCCTG>TTTTCCCTACAGACCAATACAGAAACCTCCCTGC | Missense Mutation (DEL) | VAF 8/26 reads (31%) | called by mutect2*, pindel, varscan2*
- KIF4B | c.1633C>G p.Q545E | Missense Mutation (SNP) | VAF 124/311 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- LRFN5 | c.304_305insT p.R102Mfs*7 | Frame Shift Ins (INS) | VAF 108/292 reads (37%) | called by mutect2, pindel, varscan2
- MGAT5 | c.1111C>T p.Q371* | Nonsense Mutation (SNP) | VAF 67/155 reads (43%) | called by muse, mutect2, varscan2
- MYH1 | c.5094G>C p.Q1698H | Missense Mutation (SNP) | VAF 160/490 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- PTF1A | c.955G>C p.E319Q | Missense Mutation (SNP) | VAF 17/394 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- RNF39 | c.194C>G p.S65C | Missense Mutation (SNP) | VAF 315/951 reads (33%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- SUDS3 | c.548G>C p.R183T | Missense Mutation (SNP) | VAF 83/129 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- SUV39H1 | c.320C>T p.P107L | Missense Mutation (SNP) | VAF 200/635 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- UBE2D1 | c.65C>T p.S22L | Missense Mutation (SNP) | VAF 37/304 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- ASB4 | c.879G>A p.L293= | Silent (SNP) | VAF 241/510 reads (47%) | called by muse, mutect2, varscan2
- BATF | c.249G>A p.T83= | Silent (SNP) | VAF 261/526 reads (50%) | called by muse, mutect2, varscan2
- BTNL3 | c.171G>A p.R57= | Silent (SNP) | VAF 191/479 reads (40%) | called by muse, mutect2, varscan2
- C4B | c.3981C>G p.L1327= | Silent (SNP) | VAF 32/186 reads (17%) | called by mutect2, varscan2
- DACH2 | c.1077C>G p.L359= | Silent (SNP) | VAF 117/300 reads (39%) | called by muse, mutect2, varscan2
- DUSP9 | c.72C>G p.L24= | Silent (SNP) | VAF 261/705 reads (37%) | called by muse, mutect2, varscan2
- FSCB | c.873C>G p.V291= | Silent (SNP) | VAF 14/482 reads (3%) | catalogued as COSV61219155; called by muse, mutect2
- IGHV3-53 | chr14:106592675 ins TTTGA | 3'Flank (INS) | VAF 61/72 reads (85%) | called by mutect2, pindel, varscan2
- TRGJP | chr7:38276318 ins ATC | 5'Flank (INS) | VAF 76/86 reads (88%) | called by mutect2, pindel, varscan2
